Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LH, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LH-01A (Primary Tumor).

[page 1 of 2]
Procedure: adrenalectomy

Gross description: 11 x 6 x 4.5cm, 290g

Diagnosis: adrenocortical carcinoma, 1 per 10 hpf

Reference Pathology: none

ICD-O-3

Tumor, Adrenal Cortical of
unknown/uncertain behavior

8370/3

Site: Adrenal Gland Cortex
C74.0

2/21/13

Process - if case passes we can
request more path. May not ship
if not malignant.

Criteria	11/14/13	Yes	No
Dis. or Synchronous Primary Noted			
Case is for review	QUALIFIED		

[page 2 of 2]
Patient # from Tissue Source Site

Date of report

Date of Surgery/specimen collection

Site (confirmed to be adrenal) with laterality indicated

Tumor size(s)

11x6x4.5cm

Histologic diagnosis

ACC

Lymph Node Status

X

Pathologic information

Weiss score

Source: NCI Genomic Data Commons file 088f8a60-a973-40e7-8b96-8309ee9df85a (TCGA-OR-A5LH.093D8D72-8D1B-4C23-A132-D0DCBB05DE26.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).